Gene-level copy-number profile of specimen HCM-SANG-0313-C15-85A from HCMI case HCM-SANG-0313-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0313-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8b9b2892-6404-43e2-83c8-2f0f3a1ef98f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0313-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/77a5d361-25ae-49c5-856c-b146c8c65129

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,775; copy number 2: 16,293; copy number 3: 26,136; copy number 4: 7,580; copy number 5: 4,259; copy number 6: 1,914; copy number 7: 578; copy number 8: 281; copy number 9: 31; copy number 10: 15; copy number 11: 28.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 933 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:224,114,111–224,228,043, 6 genes, copy number 7 (within-gene range 5–7): FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4.
- chr1:234,527,887–234,593,402, 3 genes, copy number 7: LINC01354, AL161640.1, U8.
- chr2:43,219,849–43,233,394, 4 genes, copy number 8 (within-gene range 4–8): AC010883.3, ZFP36L2, LINC01126, AC010883.1.
- chr3:185,914,558–185,980,872, 2 genes, copy number 7: TRA2B, NMRAL2P.
- chr5:142,592,178–142,761,035, 3 genes, copy number 7 (within-gene range 4–7): FGF1, AC005592.1, LINC01844.
- chr6:29,657,002–30,364,280, 67 genes, copy number 8 (broad region; genes not listed).
- chr6:42,879,616–43,288,258, 26 genes, copy number 8–9: RPL7L1, C6orf226, PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1.
- chr6:43,477,523–45,664,349, 53 genes, copy number 7–11: TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1.
- chr6:46,852,522–47,753,240, 14 genes, copy number 7: ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1.
- chr6:139,677,639–139,860,476, 1 gene, copy number 7 (within-gene range 5–7): FILNC1.
- chr7:7,293,508–7,293,880, 1 gene, copy number 7: AC079448.1.
- chr8:109,573,978–109,691,791, 2 genes, copy number 7: SYBU, AC079061.1.
- chr9:124,001,670–124,033,301, 1 gene, copy number 8 (within-gene range 3–8): LHX2.
- chr9:124,031,624–124,032,524, 1 gene, copy number 8: AC006450.2.
- chr11:5,967,177–5,968,494, 1 gene, copy number 7: OR56A5.
- chr11:9,573,670–9,752,993, 7 genes, copy number 8: WEE1, AC122179.1, RPL23AP65, AC011979.2, AC011979.1, SWAP70, RN7SKP50.
- chr11:10,507,894–10,541,230, 3 genes, copy number 7: MTRNR2L8, MIR4485, RNF141.
- chr13:24,680,408–24,712,472, 3 genes, copy number 7: ATP12A, RNY1P7, RPL26P34.
- chr13:42,562,736–42,814,897, 3 genes, copy number 7: TNFSF11, FAM216B, LINC01050.
- chr14:49,057,713–50,335,558, 43 genes, copy number 7–9 (within-gene range 3–9): AL110505.1, ATP5MC2P2, RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L.
- chr15:79,989,905–80,015,707, 2 genes, copy number 9: AC015871.5, AC092701.1.
- chr15:90,001,324–90,082,206, 1 gene, copy number 7 (within-gene range 6–7): ZNF710.
- chr15:90,024,955–90,138,016, 5 genes, copy number 7: AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT.
- chr17:39,757,718–39,864,312, 3 genes, copy number 9: IKZF3, KRT8P34, AC090844.1.
- chr17:58,166,982–58,268,518, 7 genes, copy number 9: OR4D2, EPX, AC005962.1, MKS1, LPO, AC005962.2, AC004687.3.
- chr18:45,034–15,197,775, 363 genes, copy number 7 (broad region; genes not listed).
- chr18:45,825,675–45,844,094, 1 gene, copy number 9: SIGLEC15.
- chr18:52,336,361–61,579,456, 138 genes, copy number 8 (broad region; genes not listed).
- chr19:2,249,309–2,341,172, 9 genes, copy number 8 (within-gene range 2–8): AMH, MIR4321, JSRP1, OAZ1, AC005258.1, PEAK3, LINGO3, AC104530.1, AC005258.2.
- chr19:32,581,190–34,860,747, 79 genes, copy number 7 (broad region; genes not listed).
- chr19:35,248,330–35,745,445, 41 genes, copy number 7: LSR, AC002128.2, AC002128.1, USF2, HAMP, MAG, CD22, U62631.1, MIR5196, FFAR1, FFAR3, GPR42, EEF1A1P7, LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN, SBSN, GAPDHS, TMEM147-AS1, TMEM147, ATP4A, AD000090.1, LINC01766, AC002115.1, HAUS5, RBM42, ETV2, COX6B1, UPK1A, UPK1A-AS1, TYMSP2, ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4.
- chr19:45,306,413–45,645,602, 17 genes, copy number 7–8: CKM, RPS16P9, KLC3, ERCC2, PPP1R13L, POLR1G, ERCC1, MIR6088, FOSB, RTN2, PPM1N, VASP, OPA3, GPR4, EML2, MIR330, EML2-AS1.
- chr19:48,485,271–48,513,935, 1 gene, copy number 9: LMTK3.
- chr20:45,109,452–45,490,248, 22 genes, copy number 7: WFDC5, WFDC12, PI3, SEMG1, SEMG2, AL035660.1, AL035660.2, SLPI, MATN4, RBPJL, SDC4, AL021578.1, SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2.

Autosomal genes at a single copy (total copy number 1): 753. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
